Surgical pathology report (de-identified scan), TCGA case TCGA-77-8138, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8138-01A (Primary Tumor).

[page 1 of 2]
See supplementary report below, [REDACTED]

HISTORY

(R) upper lobectomy. NSCLC.

MACROSCOPIC

One specimen received.

The specimen is labelled "left upper lobe" and consists of a lobe of lung measuring 152 x 90 x 40 mm. There is an obvious tumour mass within the specimen and there is puckering of the overlying pleura. There is fat adherent to the pleura in this area. Sectioning the specimen reveals a large tumour mass measuring 50 x 34 x 50 mm in maximal extent. There is prominent cavitation of this tumour centrally. The adjacent lung is unremarkable. No endobronchial lesions are seen. [1A, bronchial resection margin; 1B-1C, peribronchial lymph nodes; 1D-1F, RS of tumour with pleura; 1G, uninvolved lung.]

MICROSCOPY

Sections show a moderately to poorly differentiated squamous cell carcinoma with extensive central necrosis. There is invasion of the pleura but not of overlying chest wall fat, and soft tissue resection margins are clear of malignancy. Vascular invasion is identified but no lymphatic permeation is seen and no perineural infiltration is found. Peribronchial lymph nodes show no evidence of metastatic carcinoma. The bronchial resection margin is well clear of malignancy and shows no evidence of squamous metaplasia or dysplasia. Distant lung parenchyma shows emphysema while lung parenchyma adjacent to the tumour shows organising obstructive pneumonitis.

SUMMARY

Right upper lobectomy:

Moderately to poorly differentiated squamous cell carcinoma, 50 mm in diameter.

Pleural and vascular invasion present.

No lymphatic or perineural invasion found.

No lymph metastases.

Pathological stage T2 N0.

cc: Lung Cancer Registry

SUPPLEMENTARY REPORT

[page 2 of 2]
Please note that the specimen was a left upper lobectomy, as indicated on the specimen container, not a right upper lobe as stated on the request slip.

SUMMARY

Left upper lobectomy:

Moderately to poorly differentiated squamous cell carcinoma, 50 mm in diameter.

Pleural and vascular invasion present.

No lymphatic or perineural invasion found.

No lymph metastases.

Pathological stage T2 N0.

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

Source: NCI Genomic Data Commons file 4f82c878-2d75-4e80-ac42-c65d5db42afc (TCGA-77-8138.FAB5161E-1A7A-4074-84E5-ADDBA1379E1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).